Somatic mutation profile of tumor specimen TCGA-06-0749-01A (aliquot TCGA-06-0749-01A-01D-1492-08) from TCGA case TCGA-06-0749, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 50.8 years (18,571 days).
Specimen TCGA-06-0749-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 42609f45-611a-49ae-85ea-5784ff813e84.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0749-10A (Blood Derived Normal), aliquot TCGA-06-0749-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e4b23974-99df-4788-bdc3-947dab6b1e19

The open-access MAF lists 55 somatic variants for this specimen: 43 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 34, Silent 12, Nonsense Mutation 4, Frame Shift Del 3, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 39/161 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs769696078, COSV51770322, COSV99297135; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADCY5 | c.2213G>A p.R738H | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.041); catalogued as rs1324655717, COSV59193487, COSV59200545; called by muse, mutect2, varscan2
- AK7 | c.997T>C p.F333L | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV50874149; called by muse, mutect2, varscan2
- ANKFN1 | c.889G>A p.V297I | Missense Mutation (SNP) | VAF 30/175 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs777136761, COSV59451736; called by muse, mutect2, varscan2
- ARHGAP30 | c.610G>A p.V204M | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs149577194; called by muse, mutect2, varscan2
- BIRC6 | c.6468T>A p.H2156Q | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV70202019; called by muse, mutect2
- BNC2 | c.2983G>A p.G995R | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.636); catalogued as rs143124811; called by muse, mutect2, varscan2
- CLCN1 | c.2642G>A p.R881H | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs753106925, COSV58371407, COSV58373618; called by muse, mutect2, varscan2
- CREBBP | c.1256G>A p.W419* | Nonsense Mutation (SNP) | VAF 45/163 reads (28%) | catalogued as COSV52129560; called by muse, mutect2, varscan2
- CYP4F2 | c.1304C>T p.P435L | Missense Mutation (SNP) | VAF 46/258 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as rs550261161, COSV55619400, COSV99685655; called by muse, mutect2
- DAG1 | c.895A>G p.I299V | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.078); catalogued as COSV58185337; called by muse, mutect2, varscan2
- ECE2 | c.176C>T p.T59M | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as rs1228570426, COSV62566753; called by muse, mutect2, varscan2
- EGFR | c.2320G>A p.V774M | Missense Mutation (SNP) | VAF 34/297 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs567477136, COSV51777313, COSV51843665; called by muse, mutect2, varscan2
- FGD5 | c.2173T>A p.Y725N | Missense Mutation (SNP) | VAF 47/144 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.189); catalogued as COSV53246299; called by muse, mutect2, varscan2
- FUT8 | c.91C>T p.R31* | Nonsense Mutation (SNP) | VAF 46/152 reads (30%) | catalogued as COSV61287028; called by muse, mutect2, varscan2
- KCNB2 | c.1324C>T p.R442W | Missense Mutation (SNP) | VAF 52/176 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750665772, COSV73051163; called by muse, varscan2
- KCNJ15 | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 65/191 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772620107, COSV60810335; called by muse, mutect2, varscan2
- KRT16 | c.727G>A p.G243S | Missense Mutation (SNP) | VAF 53/169 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as rs370377321; called by muse, mutect2, varscan2
- LCE2C | c.286C>A p.P96T | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as rs199924989, COSV64228505; called by muse, mutect2, varscan2
- LCMT1 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs995675568, COSV66725785; called by muse, mutect2, varscan2
- MCM7 | c.1198C>T p.R400C | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751951140, COSV57995022; called by muse, mutect2, varscan2
- MYO1B | c.2767T>C p.C923R (on ENST00000304164; = p.C865R on NM_012223.5) | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58433490; called by muse, mutect2, varscan2
- NLRP3 | c.2738C>T p.T913M | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.154); catalogued as rs765925466, COSV60219292, COSV60225201; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NUP210L | c.2200C>T p.R734* | Nonsense Mutation (SNP) | VAF 52/148 reads (35%) | catalogued as rs771522844, COSV55141015; called by muse, varscan2
- OPRL1 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV61092104; called by muse, mutect2, varscan2
- OR10W1 | c.654G>T p.K218N | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV67720164, COSV67720583; called by muse, mutect2, varscan2
- OR2H1 | c.859G>A p.V287I | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759165826, COSV65810709; called by muse, mutect2, varscan2
- OR4D5 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 107/366 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.199); catalogued as rs142766960, COSV58305795; called by muse, mutect2, varscan2
- OR8K3 | c.838G>T p.V280F | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.966); catalogued as COSV57131412; called by muse, mutect2, varscan2
- OTOF | c.1412A>G p.K471R | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV55507928; called by muse, mutect2, varscan2
- PGM5 | c.1594G>A p.G532S | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs182577861; called by muse, mutect2, varscan2
- PLEKHG7 | c.1426C>T p.R476W | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as rs115752910, COSV60821400; called by muse, mutect2, varscan2
- PPEF2 | c.1600G>A p.V534M | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as rs763143738, COSV54423837; called by muse, mutect2, varscan2
- RIPK1 | c.994C>T p.R332W | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.922); catalogued as rs370418004; called by muse, mutect2, varscan2
- RPL22 | c.44dup p.K16Efs*9 | Frame Shift Ins (INS) | VAF 14/51 reads (27%) | catalogued as rs759765382; called by mutect2, varscan2
- TAF1B | c.306C>T p.N102= | Splice Region (SNP) | VAF 24/104 reads (23%) | catalogued as rs376441869; called by muse, mutect2, varscan2
- TAF1L | c.3754C>T p.R1252W | Missense Mutation (SNP) | VAF 91/155 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54259076; called by muse, mutect2, varscan2
- TNRC18 | c.2200C>T p.R734W | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs776348892, COSV68166748; called by muse, mutect2
- UMODL1 | c.1227C>A p.H409Q | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.222); catalogued as rs754877661, COSV61160815; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.854dup p.Y285* | Nonsense Mutation (INS) | VAF 30/128 reads (23%) | called by mutect2, pindel, varscan2
- PCLO | c.8083del p.S2695Pfs*2 | Frame Shift Del (DEL) | VAF 19/89 reads (21%) | called by mutect2, pindel, varscan2
- PTEN | c.889del p.D297Ifs*10 | Frame Shift Del (DEL) | VAF 41/104 reads (39%) | called by mutect2, pindel, varscan2
- STAG2 | c.2407_2408del p.M803Vfs*5 | Frame Shift Del (DEL) | VAF 104/206 reads (50%) | called by mutect2, pindel, varscan2
- ADGRD1 | c.2475G>A p.S825= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as rs754268247, COSV55449423; called by muse, mutect2, varscan2
- ARHGEF10L | c.2892C>T p.P964= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs749642671, COSV51435443, COSV99392841; called by muse, mutect2, varscan2
- ASZ1 | c.1005A>G p.V335= | Silent (SNP) | VAF 10/101 reads (10%) | catalogued as rs773571018, COSV52914252; called by muse, mutect2, varscan2
- CASR | c.648C>T p.D216= | Silent (SNP) | VAF 58/236 reads (25%) | catalogued as rs774470582, COSV56134230; ClinVar: likely benign; called by muse, mutect2, varscan2
- CEP112 | c.2181G>A p.E727= | Silent (SNP) | VAF 24/91 reads (26%) | catalogued as COSV67141781; called by muse, varscan2
- CERS4 | c.342C>G p.T114= | Silent (SNP) | VAF 23/77 reads (30%) | catalogued as COSV52168218; called by muse, mutect2, varscan2
- GABBR1 | c.234C>T p.V78= | Silent (SNP) | VAF 35/179 reads (20%) | catalogued as rs1562129796, COSV63543266; called by muse, mutect2, varscan2
- KIF2B | c.555C>T p.Y185= | Silent (SNP) | VAF 40/145 reads (28%) | catalogued as rs369155067, COSV52132496; called by muse, mutect2, varscan2
- LRIG3 | c.1896C>A p.P632= | Silent (SNP) | VAF 36/135 reads (27%) | catalogued as COSV57866269; called by muse, mutect2, varscan2
- RAMP3 | c.138C>T p.D46= | Silent (SNP) | VAF 18/152 reads (12%) | catalogued as COSV54246087; called by muse, mutect2, varscan2
- RBM47 | c.552C>T p.Y184= | Silent (SNP) | VAF 59/210 reads (28%) | catalogued as rs779152879, COSV55936286; called by muse, mutect2, varscan2
- STAB2 | c.342T>G p.G114= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV66341749; called by muse, mutect2, varscan2
